Somatic mutation profile of tumor specimen 0DLJX1 from CCDI case PBBWYY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.7 years (3,560 days).
Specimen 0DLJX1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c427034f-0945-40a1-ac48-802814cb17c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLJWK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d34d721d-f083-48db-b1b9-8d60d7b20b05

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM47B | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 169/923 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs370213556, COSV61453664; called by muse, mutect2, varscan2
- PCDH1 | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 295/1561 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1288930806; called by muse, mutect2, varscan2
- CYP2B6 | c.18C>T p.L6= | Silent (SNP) | VAF 378/1437 reads (26%) | called by muse, mutect2, varscan2
